Somatic mutation profile of tumor specimen TCGA-QR-A703-01A (aliquot TCGA-QR-A703-01A-11D-A35D-08) from TCGA case TCGA-QR-A703, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 23.1 years (8,421 days).
Specimen TCGA-QR-A703-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9729f4f4-38be-4c22-a640-6f8f89b26516.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A703-10A (Blood Derived Normal), aliquot TCGA-QR-A703-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4fa2551-ae45-4ed4-99f6-0c2628066deb

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Nonsense Mutation 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SSTR3 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as rs1459907072, COSV60728737; called by muse, mutect2, varscan2
- AGBL2 | c.1058G>A p.W353* | Nonsense Mutation (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2
